Somatic mutation profile of tumor specimen 3a380577-c134-47ba-a1ce-988d7c (aliquot 3a380577-c134-47ba-a1ce-988d7c_D6) from CPTAC case 20OV005, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 3a380577-c134-47ba-a1ce-988d7c: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74a7b70a-04e7-4227-a569-948644c634a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen e20828d6-1399-43d5-96de-21ae37 (Blood Derived Normal), aliquot e20828d6-1399-43d5-96de-21ae37_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66597b74-1450-4e26-b769-ca2206348bd0

The open-access MAF lists 78 somatic variants for this specimen: 48 protein-altering or splice-affecting, 19 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 19, Nonsense Mutation 4, RNA 4, Intron 3, Splice Site 2, Frame Shift Del 1, Frame Shift Ins 1, 3'UTR 1, 3'Flank 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPRS | c.4756G>A p.V1586M | Missense Mutation (SNP) | VAF 97/247 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs140472977; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 197/284 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARHGAP31 | c.2626G>T p.E876* | Nonsense Mutation (SNP) | VAF 202/951 reads (21%) | catalogued as COSV51795283; called by muse, mutect2, varscan2
- ARID2 | c.3197C>T p.P1066L | Missense Mutation (SNP) | VAF 106/1068 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1004162984, COSV57599724; called by muse, mutect2
- C20orf194 | c.982-1G>T p.X328_splice | Splice Site (SNP) | VAF 13/58 reads (22%) | catalogued as COSV99330503; called by mutect2, varscan2
- CAT | c.1196-1G>T p.X399_splice | Splice Site (SNP) | VAF 111/481 reads (23%) | catalogued as COSV53813966; called by muse, mutect2, varscan2
- CYP3A4 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.169); catalogued as rs145582851; called by muse, mutect2, varscan2
- DCAF4L2 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 82/553 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100151281, COSV60477090; called by muse, mutect2, varscan2
- DNHD1 | c.4808G>A p.R1603H | Missense Mutation (SNP) | VAF 25/537 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763741199; called by muse, mutect2
- DOK2 | c.287C>A p.A96E | Missense Mutation (SNP) | VAF 146/340 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1480070528, COSV52389148; called by muse, varscan2
- EPHA5 | c.1336G>A p.G446R | Missense Mutation (SNP) | VAF 116/339 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56628609; called by muse, mutect2, varscan2
- LAMA3 | c.5632C>T p.R1878C (on ENST00000313654 / NM_198129.4; = p.R269C on NM_000227.6) | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs867507379, COSV52535466; called by muse, mutect2, varscan2
- LSR | c.1246G>A p.D416N (on ENST00000361790; = p.D397N on NM_015925.6) | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs372794690; called by muse, mutect2, varscan2
- MATN2 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 150/862 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs775044061; called by muse, mutect2, varscan2
- MNDA | c.748A>G p.K250E | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63741729; called by muse, mutect2, varscan2
- MYH13 | c.1231G>T p.E411* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as COSV52846363; called by muse, mutect2, varscan2
- OR2B2 | c.904A>G p.K302E | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as rs967027358, COSV100308289; called by muse, mutect2, varscan2
- PRDM2 | c.3763A>G p.T1255A | Missense Mutation (SNP) | VAF 94/123 reads (76%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV52444915; called by muse, mutect2, varscan2
- SKI | c.1933C>T p.R645W | Missense Mutation (SNP) | VAF 108/254 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66013222; called by muse, mutect2, varscan2
- TNPO3 | c.1645G>A p.D549N | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as rs1004889227, COSV55286731; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TYSND1 | c.1373C>T p.S458L | Missense Mutation (SNP) | VAF 68/327 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200428388; called by muse, mutect2, varscan2
- WIF1 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs781329359, COSV54129763, COSV99682998; called by muse, mutect2, varscan2
- ZNF541 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs1568501086; called by muse, mutect2, varscan2
- ANKRD30A | c.3063A>C p.E1021D (on ENST00000611781; = p.E965D on NM_052997.2) | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2
- ARHGAP31 | c.2625G>T p.E875D | Missense Mutation (SNP) | VAF 199/920 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by mutect2, varscan2
- C8G | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- CFAP20DC | c.1708C>G p.L570V | Missense Mutation (SNP) | VAF 77/385 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH2 | c.1543C>G p.L515V | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EEA1 | c.1059G>T p.L353F | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HS6ST1 | c.814A>T p.K272* | Nonsense Mutation (SNP) | VAF 240/1037 reads (23%) | called by muse, mutect2, varscan2
- IL21R | c.228T>A p.H76Q | Missense Mutation (SNP) | VAF 196/718 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- LMF1 | c.1217A>G p.Y406C | Missense Mutation (SNP) | VAF 74/310 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEE1 | c.2842C>A p.H948N | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2
- MAP6D1 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MET | c.2526G>T p.K842N | Missense Mutation (SNP) | VAF 91/345 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- NBPF11 | c.622G>T p.A208S | Missense Mutation (SNP) | VAF 138/1086 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.918); called by mutect2, varscan2
- PTPRQ | c.3755C>A p.S1252* (on ENST00000616559; = p.S1210* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2
- RAB35 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 85/424 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- RELB | c.503A>T p.E168V | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- RPS15 | c.89+7G>C | Splice Region (SNP) | VAF 19/168 reads (11%) | called by muse, mutect2, varscan2
- SORCS1 | c.2349dup p.Q784Tfs*23 | Frame Shift Ins (INS) | VAF 40/142 reads (28%) | called by mutect2, pindel, varscan2
- SPAG4 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- SPDL1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPSB2 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 86/768 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- TNFAIP6 | c.493A>C p.I165L | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.2272A>C p.N758H | Missense Mutation (SNP) | VAF 54/252 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- TRPV5 | c.735del p.K245Nfs*10 | Frame Shift Del (DEL) | VAF 42/154 reads (27%) | called by mutect2, varscan2
- ZBTB38 | c.2041G>A p.A681T | Missense Mutation (SNP) | VAF 60/393 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ALDH1L1 | c.882G>A p.L294= | Silent (SNP) | VAF 70/317 reads (22%) | called by muse, mutect2, varscan2
- ARHGAP31 | c.2466G>A p.L822= | Silent (SNP) | VAF 126/726 reads (17%) | catalogued as COSV51792636; called by muse, mutect2, varscan2
- DCBLD1 | c.390C>T p.V130= | Silent (SNP) | VAF 44/142 reads (31%) | called by muse, mutect2, varscan2
- DNAH11 | c.7158C>T p.C2386= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs1433039063; called by muse, varscan2
- EIF4G1 | c.3901C>T p.L1301= (on ENST00000346169 / NM_198241.3; = p.L1106= on NM_004953.5) | Silent (SNP) | VAF 261/1083 reads (24%) | catalogued as rs775173207; called by muse, mutect2, varscan2
- FLNC | c.2538G>T p.L846= | Silent (SNP) | VAF 163/734 reads (22%) | catalogued as rs766913091; called by muse, mutect2, varscan2
- HTT | c.9207C>G p.V3069= | Silent (SNP) | VAF 47/127 reads (37%) | catalogued as rs745832191, COSV61861620; called by muse, mutect2, varscan2
- HYDIN | c.11649C>T p.A3883= | Silent (SNP) | VAF 103/204 reads (50%) | catalogued as rs547639554; called by muse, mutect2, varscan2
- KIF6 | c.2151T>C p.H717= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as rs781485675; called by muse, mutect2, varscan2
- LONP1 | c.45G>C p.R15= | Silent (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- MFSD3 | c.75C>T p.L25= | Silent (SNP) | VAF 42/298 reads (14%) | called by muse, mutect2, varscan2
- RSPO3 | c.262C>A p.R88= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as COSV100759428; called by muse, mutect2, varscan2
- SCARF1 | c.1722C>T p.F574= | Silent (SNP) | VAF 54/150 reads (36%) | catalogued as rs544558021, COSV53957590; called by muse, mutect2, varscan2
- SLC22A13 | c.1332C>T p.F444= | Silent (SNP) | VAF 81/200 reads (41%) | called by muse, mutect2, varscan2
- SOX18 | c.894G>T p.S298= | Silent (SNP) | VAF 5/76 reads (7%) | called by muse, mutect2
- SPDL1 | c.522G>A p.E174= | Silent (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2
- TRIM58 | c.1197A>T p.S399= | Silent (SNP) | VAF 269/668 reads (40%) | called by muse, mutect2, varscan2
- ZEB2 | c.1911A>C p.S637= | Silent (SNP) | VAF 87/295 reads (29%) | called by mutect2, varscan2
- ZNF33B | c.2283G>A p.K761= | Silent (SNP) | VAF 43/163 reads (26%) | called by muse, mutect2, varscan2
- AC093791.1 | n.442A>G | RNA (SNP) | VAF 23/69 reads (33%) | called by muse, mutect2, varscan2
- AC139795.1 | n.1767T>G | RNA (SNP) | VAF 29/144 reads (20%) | called by muse, mutect2, varscan2
- GSPT1 | c.-63+124C>T | Intron (SNP) | VAF 47/167 reads (28%) | catalogued as rs745710359; called by muse, mutect2, varscan2
- LINC00470 | n.1377C>A | RNA (SNP) | VAF 21/82 reads (26%) | called by muse, varscan2
- MPDU1 | chr17:7583730 G>A | 5'Flank (SNP) | VAF 43/101 reads (43%) | catalogued as rs911407743; called by muse, mutect2, varscan2
- RN7SL214P | chr15:77915257 C>G | 3'Flank (SNP) | VAF 38/210 reads (18%) | called by muse, mutect2
- SMTN | c.1633-1427C>A | Intron (SNP) | VAF 29/83 reads (35%) | catalogued as rs745556466; called by muse, mutect2, varscan2
- STAG3L2 | n.1414G>C | RNA (SNP) | VAF 26/238 reads (11%) | called by muse, mutect2, varscan2
- SUPT5H | c.-8A>C | 5'UTR (SNP) | VAF 22/250 reads (9%) | called by muse, mutect2
- TMEM135 | c.*2281A>T | 3'UTR (SNP) | VAF 23/98 reads (23%) | called by muse, mutect2, varscan2
- USH1C | c.1284+7584C>T | Intron (SNP) | VAF 31/124 reads (25%) | catalogued as COSV99139422; called by muse, mutect2, varscan2
